Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A3CK, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A3CK-01A (Primary Tumor).

[page 1 of 3]
Latest Version

Name

Encounter Number

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Ordering Provider

Status

Time Received

Order Number

Lab Patient Demographics

(for verification purposes)

1 CD-0-3

carcinoma, hepatocellular, NOS 8170/3

Site: liver C22.0

Results

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Final

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

lw
10/15/11

Specimen Description
A. Gallbladder
B. Liver section 5 - 6

Clinical Information

A. year old male with hepatocellular carcinoma related to chronic hepatitis B infection.

Diagnosis

A: Gallbladder, Cholecystectomy:
- Unremarkable gallbladder

B: Liver, Partial Resection:
- Hepatocellular carcinoma (see synoptic report)
- Focal vascular invasion present
- Resection margin free of carcinoma
- Bile duct adenoma

HPA Discrepancy		

[page 2 of 3]
Reported by:

Synoptic Report

B: Liver, Resection, Macroscopic

Specimen:

Liver

Gallbladder

PROCEDURE:

Partial hepatectomy

*Minor hepatectomy (less than 3 segments)

TUMOR SIZE:

Greatest dimension: 2.5 cm

*Additional dimensions: 2.3 x 2.2 cm

TUMOR FOCALITY:

Solitary (specify location): segments 5, 6

B: Liver, Resection, Microscopic

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

TUMOR EXTENSION (select all that apply):

Tumor confined to liver

PRIMARY TUMOR (pT):

pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 12 mm

*VENOUS (LARGE VESSEL) INVASION (V):

*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Cirrhosis/fibrosis

*Hepatitis (specify type): b

*COMMENT(S):

There are tumor emboli in the small vessels adjacent to the tumor mass.

Gross Description

Received are specimens A to B. All requisitions and specimen containers are labelled with the patient's name The cassettes and AP identifiers are labelled with the Surgical Number

A. The specimen is received fresh, subsequently placed into formalin and consists of an intact gallbladder measuring 8.0 x 3.5 x 2.5 cm. The serosal surface is tan and smooth. The lumen contains bile and multiple friable yellow calculi measuring up to 0.2 cm in thickness. The mucosal surface is bile stained and velvety with areas of yellow speckling. The wall averages 0.2 cm in thickness. The cystic duct is patent. The cystic

[page 3 of 3]
duct lymph node is not grossly identified. Representative sections are submitted in one cassette.

B. The specimen is originally received fresh, subsequently placed into formalin and consists of a portion of liver weighing 199.4 grams and measuring 12.7 x 9.0 x 5.5 cm. The resection margin is dyed blue. The capsular surface is slightly nodular. Upon

sectioning, two firm tan nodules are identified. The smaller nodule measures 0.8 x 0.7 x 0.5 cm. This nodule grossly involves the blue-painted resection margin and comes to within 0.5 cm of the capsular surface. The second mass measures 2.5 x 2.3 x 2.2 cm. This mass is 2.0 cm from the first mass and grossly comes to within less than 0.1 cm from the capsular surface and 1.2 cm from the blue-painted resection margin. The remainder of the liver parenchyma is grossly unremarkable.

Representative sections are submitted as follows:

B1	section of the smallest mass in relation to the blue-painted resection margin
B2	section of the smaller mass in relation to the capsular surface
B3	section of grossly unremarkable liver between the first and second mass
B4	section of the second mass in relation to the capsular surface

B5	section of the second mass in relation to the blue-painted resection margin
B6	further section of the second mass
B7	section of grossly unremarkable liver

Please note, sections have been taken for tumor banking.

Additional Information

Accession Number

Encounter Number

Patient Location

Source: NCI Genomic Data Commons file 97408b07-eae4-46c3-bce8-5deda74093e8 (TCGA-G3-A3CK.ED5E5458-1E88-4126-B46B-96297F5A0FFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).